MMRF case MMRF_1045 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6b1817f8-d665-4278-8021-b355eb035569

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.3 years (29,713 days); Days to last known disease status: 609 days (1.7 years); Days to last follow up: 609 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 229 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 322 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 0): M Protein 4.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 134 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.275 mg/dL; Immunoglobulin G 47.7 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 5.08 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 10.4 g/dL; Glucose 5.17 mmol/L.
- Day 74: M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.74 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.95 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 165 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.605 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.04 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 229 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 6.25 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.35 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 6.05 mmol/L.
- Day 336 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.93 mg/dL; Immunoglobulin G 9.74 g/L; Immunoglobulin A 2.69 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 5.6 µkat/L; Hemoglobin 4.46 mmol/L; Leukocytes 16.2 ×10⁹/L; Absolute Neutrophil 5.83 ×10⁹/L; Platelets 53 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 446 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 523 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 3.69 mmol/L.
- Day 609 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 5.08 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -30: Weight: 64 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1045_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
- Sample MMRF_1045_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -30 days.
